Somatic mutation profile of tumor specimen C3L-00103-01 (aliquot CPT0000630006) from CPTAC case C3L-00103, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 56.4 years (20,598 days).
Specimen C3L-00103-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f199cd3e-e1cc-4fd7-8a8f-23f7955fca58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00103-31 (Blood Derived Normal), aliquot CPT0003850002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/258f9143-27e7-441a-a150-096316896786

The open-access MAF lists 43 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 13, Frame Shift Ins 3, RNA 1, Frame Shift Del 1, Intron 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 155/422 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as rs5030828, CM011823, COSV56542730; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- GRM3 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 87/342 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446375, COSV64469346; called by muse, mutect2, varscan2
- INPP5D | c.1301C>T p.T434M (on ENST00000445964 / NM_001017915.3; = p.T433M on NM_005541.5) | Missense Mutation (SNP) | VAF 145/586 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1455642398, COSV64039767; called by muse, mutect2, varscan2
- NR2F1 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 81/348 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59067477, COSV59068187; called by muse, mutect2, varscan2
- NR2F1 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 84/357 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100504734; called by muse, mutect2, varscan2
- OLAH | c.703G>A p.G235R (on ENST00000378228 / NM_001039702.3; = p.G288R on NM_018324.3) | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771190215, COSV62252434; called by muse, mutect2, varscan2
- PRDM9 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 181/636 reads (28%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.084); catalogued as COSV57009406; called by muse, mutect2, varscan2
- RNF112 | c.1664G>A p.G555E | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746780377; called by muse, mutect2
- YLPM1 | c.5425C>T p.R1809* | Nonsense Mutation (SNP) | VAF 69/223 reads (31%) | catalogued as rs748776364; called by muse, mutect2, varscan2
- CACNA1F | c.5391A>T p.A1797= | Splice Region (SNP) | VAF 18/24 reads (75%) | called by muse, mutect2, varscan2
- COL9A2 | c.2023T>C p.Y675H | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSMD1 | c.7380C>G p.C2460W (on ENST00000520002; = p.C2459W on NM_033225.6) | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.4417G>T p.D1473Y (on ENST00000297405 / NM_001363185.1; = p.D1369Y on NM_052900.3) | Missense Mutation (SNP) | VAF 114/468 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM151A | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAT3 | c.6064C>A p.P2022T | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.442); called by muse, mutect2
- KANSL1 | c.1233dup p.D412* | Frame Shift Ins (INS) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- KCNJ3 | c.458del p.D153Afs*49 | Frame Shift Del (DEL) | VAF 74/291 reads (25%) | called by mutect2, pindel, varscan2
- KIAA1328 | c.1646T>A p.L549Q | Missense Mutation (SNP) | VAF 155/602 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF26A | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- NANOS3 | c.217T>G p.S73A (on ENST00000397555; = p.S92A on NM_001098622.2) | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PDIA4 | c.1486T>G p.S496A (on ENST00000286091 / NM_001371244.1; = p.S495A on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1 | c.5603dup p.K1869* | Frame Shift Ins (INS) | VAF 76/310 reads (25%) | called by mutect2, pindel, varscan2
- ROBO1 | c.1005G>T p.M335I | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TESK1 | c.1844C>A p.P615H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- TMOD3 | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 89/356 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- UBR3 | c.3658A>G p.M1220V | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.761); called by muse, mutect2
- ZNF292 | c.6279dup p.R2094Tfs*10 | Frame Shift Ins (INS) | VAF 45/185 reads (24%) | called by mutect2, pindel, varscan2
- ZNF831 | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, varscan2
- ADCY9 | c.393C>T p.S131= | Silent (SNP) | VAF 65/226 reads (29%) | called by muse, mutect2, varscan2
- COL11A2 | c.1146G>A p.K382= (on ENST00000341947 / NM_080680.3; = p.K275= on NM_080679.2) | Silent (SNP) | VAF 162/639 reads (25%) | called by muse, mutect2, varscan2
- DRD5 | c.567C>T p.G189= | Silent (SNP) | VAF 41/175 reads (23%) | catalogued as rs1238985977, COSV100431778; called by muse, mutect2, varscan2
- GP5 | c.379T>C p.L127= | Silent (SNP) | VAF 8/218 reads (4%) | called by muse, mutect2
- HELT | c.555C>T p.S185= | Silent (SNP) | VAF 49/203 reads (24%) | called by muse, mutect2, varscan2
- KIF1A | c.3519C>T p.I1173= | Silent (SNP) | VAF 59/192 reads (31%) | called by muse, mutect2, varscan2
- LFNG | c.636G>A p.R212= (on ENST00000222725 / NM_001040167.2; = p.R83= on NM_002304.2) | Silent (SNP) | VAF 133/493 reads (27%) | called by muse, mutect2, varscan2
- LGI3 | c.1011C>A p.I337= | Silent (SNP) | VAF 65/231 reads (28%) | catalogued as rs773555136, COSV60443274; called by muse, mutect2, varscan2
- LPL | c.669C>A p.I223= | Silent (SNP) | VAF 50/526 reads (10%) | called by muse, mutect2
- PLAUR | c.225G>A p.R75= | Silent (SNP) | VAF 49/190 reads (26%) | called by muse, mutect2, varscan2
- PTPRQ | c.72T>C p.Y24= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as rs1425238900; called by muse, mutect2, varscan2
- SPRYD3 | c.936G>A p.G312= | Silent (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- TLNRD1 | c.903C>T p.L301= | Silent (SNP) | VAF 47/150 reads (31%) | catalogued as rs747666485; called by muse, mutect2, varscan2
- IL6 | c.471+72A>T | Intron (SNP) | VAF 42/143 reads (29%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1046G>A | RNA (SNP) | VAF 26/346 reads (8%) | catalogued as rs1474091255; called by muse, mutect2
